Somatic mutation profile of tumor specimen TCGA-BQ-5886-01A (aliquot TCGA-BQ-5886-01A-11D-1589-08) from TCGA case TCGA-BQ-5886, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 75.8 years (27,670 days).
Specimen TCGA-BQ-5886-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8fbc89a-bc40-4889-bf89-ea838e03a569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5886-11A (Solid Tissue Normal), aliquot TCGA-BQ-5886-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6b40990-c634-46ba-9daa-6b162e7524ae

The open-access MAF lists 65 somatic variants for this specimen: 54 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 10, Frame Shift Del 5, Splice Site 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF1 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51947185; called by muse, mutect2, varscan2
- AHNAK | c.11573G>A p.G3858D | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57225560; called by muse, mutect2
- ARHGEF12 | c.2712G>T p.K904N | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63106706; called by muse, mutect2, varscan2
- ATG2B | c.5177T>A p.L1726H | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55891778; called by muse, mutect2, varscan2
- BCAM | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV54301380; called by muse, mutect2, varscan2
- BHMT | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57155420; called by muse, mutect2, varscan2
- C10orf62 | c.40T>A p.S14T | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV65705498; called by muse, mutect2
- CAPN9 | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV55238126; called by muse, mutect2, varscan2
- DENND2B | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1305782218, COSV58206819; called by muse, mutect2, varscan2
- DNM1 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV57855179; called by muse, mutect2, varscan2
- EIF2S3 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as COSV53407720; called by muse, mutect2, varscan2
- ELF1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV53501719; called by muse, mutect2, varscan2
- ELF3 | c.1043G>C p.R348P | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62839888; called by muse, mutect2, varscan2
- EMID1 | c.466-1G>T p.X156_splice | Splice Site (SNP) | VAF 24/92 reads (26%) | catalogued as COSV61830294, COSV61830526; called by mutect2, varscan2
- F2RL2 | c.797T>C p.L266S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56971757; called by muse, mutect2, varscan2
- FAM161A | c.1333C>T p.H445Y | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV56768175; called by muse, mutect2, varscan2
- FANCG | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1221668009, COSV62721836; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GADD45B | c.466T>A p.S156T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0.037); catalogued as COSV53126608; called by muse, mutect2, varscan2
- GAPVD1 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.219); catalogued as COSV52926360; called by muse, mutect2, varscan2
- GOLGA4 | c.1073T>C p.L358P | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62713000; called by muse, mutect2, varscan2
- GPHN | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1206432505, COSV59479715, COSV59489671; called by muse, mutect2, varscan2
- HID1 | c.1378G>C p.D460H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59352119; called by muse, mutect2
- HIVEP2 | c.4057A>G p.I1353V | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs1317202676, COSV50040329; called by muse, mutect2, varscan2
- HMGB1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV100361051, COSV58105504; called by muse, varscan2
- ITGB4 | c.4922C>T p.P1641L | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52331090; called by muse, mutect2, varscan2
- KDM6A | c.3582G>A p.W1194* | Nonsense Mutation (SNP) | VAF 26/34 reads (76%) | catalogued as COSV65038933; called by muse, mutect2, varscan2
- KIAA0100 | c.5059+2T>C p.X1687_splice | Splice Site (SNP) | VAF 56/259 reads (22%) | catalogued as COSV66495646; called by muse, mutect2, varscan2
- LMAN2L | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as COSV53843402; called by muse, mutect2, varscan2
- MON2 | c.4567G>A p.D1523N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760667289, COSV54807254, COSV54812758; called by muse, mutect2, varscan2
- MORC1 | c.785A>T p.K262I | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV51727965; called by muse, mutect2, varscan2
- NAP1L1 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV53876086; called by muse, mutect2, varscan2
- NUP205 | c.1533T>G p.I511M | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV53664386; called by muse, mutect2, varscan2
- OR8H3 | c.540C>A p.D180E | Missense Mutation (SNP) | VAF 20/329 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs755794918, COSV57910810; called by muse, mutect2
- PARD6B | c.701T>C p.M234T | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769007120, COSV65405057; called by muse, mutect2, varscan2
- PCDHB9 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.073); catalogued as rs1173996832; called by muse, mutect2, varscan2
- PFN3 | c.387A>G p.I129M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV53692649; called by muse, varscan2
- PIK3R5 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99353566; called by muse, varscan2
- PTGR1 | c.31A>C p.K11Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV53030383; called by muse, mutect2, varscan2
- PTPRA | c.1969G>T p.D657Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.208); catalogued as COSV53786437; called by muse, mutect2, varscan2
- RERE | c.3370C>G p.P1124A | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.615); catalogued as COSV61948203; called by muse, mutect2, varscan2
- SBF1 | c.5594C>G p.T1865R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53297034; called by muse, mutect2, varscan2
- SLC13A5 | c.673A>C p.T225P | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53424581; called by muse, mutect2, varscan2
- SLC6A17 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV58995722; called by muse, mutect2, varscan2
- SMC2 | c.629T>C p.L210S | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53963182; called by muse, mutect2, varscan2
- TENM2 | c.6352C>A p.R2118S (on ENST00000518659 / NM_001122679.2; = p.R1879S on NM_001080428.3) | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.44); catalogued as COSV69123403, COSV69138462; called by muse, mutect2, varscan2
- TK2 | c.485A>T p.E162V (on ENST00000299697; = p.E218V on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV55283706; called by muse, mutect2
- TUT1 | c.788A>G p.D263G | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53471500; called by muse, mutect2, varscan2
- VARS2 | c.2848G>C p.G950R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV58914151; called by muse, mutect2, varscan2
- ZFP14 | c.1247G>A p.S416N | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV54204201; called by muse, mutect2, varscan2
- HMGB1 | c.310del p.L104Sfs*48 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | called by pindel, varscan2
- NPS | c.198del p.F66Lfs*2 | Frame Shift Del (DEL) | VAF 43/329 reads (13%) | called by mutect2, pindel, varscan2
- RGS20 | c.112_114delinsC p.I38Pfs*7 | Frame Shift Del (DEL) | VAF 32/105 reads (30%) | called by pindel, varscan2*
- XAB2 | c.1632del p.I545Sfs*17 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- ZNF543 | c.357del p.Q120Nfs*16 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- CADPS2 | c.834T>C p.D278= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV57379934; called by muse, mutect2, varscan2
- CRYBG2 | c.1170T>A p.P390= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV57486274; called by muse, mutect2
- ITGAX | c.621G>A p.R207= | Silent (SNP) | VAF 100/204 reads (49%) | catalogued as COSV51649940; called by muse, mutect2, varscan2
- KMT2D | c.9309T>A p.A3103= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV56474002; called by muse, mutect2
- LRP2 | c.5736T>C p.T1912= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV55568242; called by muse, mutect2, varscan2
- PCDHB3 | c.945T>C p.Y315= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs1429601861, COSV50611570; called by muse, mutect2, varscan2
- S1PR4 | c.666C>T p.L222= | Silent (SNP) | VAF 76/241 reads (32%) | catalogued as COSV55740525, COSV55741115; called by muse, mutect2, varscan2
- TBC1D32 | c.1971A>T p.V657= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as COSV51551373; called by muse, mutect2, varscan2
- TTBK1 | c.1197C>G p.V399= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV52495265; called by muse, mutect2, varscan2
- ZFP14 | c.1248C>T p.S416= | Silent (SNP) | VAF 47/147 reads (32%) | catalogued as COSV54204186; called by muse, mutect2, varscan2
- SLC30A5 | c.274-623A>G | Intron (SNP) | VAF 8/26 reads (31%) | catalogued as rs751804271, COSV101080732; called by muse, mutect2, varscan2
